Somatic mutation profile of tumor specimen ALCH-B4NO-TTP1-A (aliquot ALCH-B4NO-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4NO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,394 days).
Specimen ALCH-B4NO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d801313-a447-4fa9-a5d4-8978f2e5616d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4NO-NB1-A (Blood Derived Normal), aliquot ALCH-B4NO-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4a8db79-1408-44d2-9fea-de397a3c370f

The open-access MAF lists 158 somatic variants for this specimen: 111 protein-altering or splice-affecting, 31 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 31, Intron 10, Nonsense Mutation 9, Splice Site 3, 5'UTR 2, Splice Region 2, 5'Flank 2, 3'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ADAMTS20 | c.5698C>T p.H1900Y | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV67133196; called by muse, mutect2
- ARHGAP15 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV54520983; called by muse, mutect2
- ARPC5 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV54172374; called by muse, mutect2
- ATAD5 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV58974006; called by muse, mutect2, varscan2
- BOD1L1 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs1331375963; called by muse, mutect2
- C12orf43 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C8orf76 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | catalogued as COSV52690094; called by muse, mutect2, varscan2
- CCDC85A | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68152812; called by muse, mutect2
- CHD8 | c.4710G>C p.L1570F (on ENST00000646647 / NM_001170629.2; = p.L1291F on NM_020920.4) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63219612; called by muse, mutect2, varscan2
- CYP24A1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 54/568 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV99398531; called by muse, mutect2
- DCK | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1401813706; called by muse, mutect2, varscan2
- DNAH5 | c.5724C>G p.I1908M | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99450218; called by muse, mutect2
- EMX1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.057); catalogued as rs917411978; called by muse, mutect2
- FADS2 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99608299; called by muse, mutect2, varscan2
- FBXO24 | c.491C>G p.S164C (on ENST00000241071 / NM_033506.3; = p.S202C on NM_012172.5) | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV53826414; called by muse, mutect2, varscan2
- GLIPR1L1 | c.719G>C p.R240T (on ENST00000378695 / NM_001304964.2; = p.R231T on NM_152779.4) | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100157362; called by muse, mutect2
- HMGCR | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV99843134; called by muse, mutect2
- IPO7 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs753786174; called by muse, varscan2
- IRS1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV59339454; called by muse, mutect2
- ITPR2 | c.4684C>G p.L1562V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV101189876, COSV67269442; called by muse, mutect2, varscan2
- KIAA1217 | c.5049G>A p.M1683I | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as rs1217958511; called by muse, mutect2, varscan2
- LIN9 | c.541C>T p.R181C (on ENST00000366808 / NM_001270410.2; = p.R126C on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100068020, COSV60243919; called by muse, mutect2
- LYPD3 | c.377C>A p.P126Q | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54988453, COSV99747073; called by muse, mutect2, varscan2
- MAP3K4 | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV62332383, COSV62336232, COSV62337762; called by muse, mutect2, varscan2
- MUC16 | c.33463C>G p.L11155V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.636); catalogued as rs749005825, COSV67441895; called by muse, mutect2, varscan2
- MUC4 | c.14465C>T p.S4822F (on ENST00000463781 / NM_018406.7; = p.S586F on NM_004532.6) | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.073); catalogued as COSV57789381; called by muse, mutect2
- NAMPT | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.039); catalogued as COSV55996762; called by muse, mutect2, varscan2
- NAV2 | c.1366C>G p.L456V (on ENST00000396087 / NM_001244963.2; = p.L433V on NM_145117.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.071); catalogued as rs749534530; called by mutect2, varscan2
- NF1 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 64/373 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.048); catalogued as rs760346063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP85 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs749399274; called by muse, varscan2
- OBSCN | c.8416G>A p.E2806K | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV52761888, COSV99486047; called by muse, mutect2, varscan2
- P3H2 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs115909080, COSV100078062, COSV60024708; called by muse, mutect2, varscan2
- PCDHB5 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); catalogued as rs267600417, COSV50648957; called by muse, mutect2
- PDE4A | c.2489C>T p.S830L (on ENST00000380702 / NM_001111307.2; = p.S591L on NM_006202.3) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs1394283274; called by muse, mutect2, varscan2
- PFKFB1 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 58/290 reads (20%) | PolyPhen benign (0.214); catalogued as rs1277580022; called by muse, varscan2
- PPP6R1 | c.845G>C p.R282T | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.055); catalogued as COSV69799405; called by muse, mutect2, varscan2
- PROS1 | c.1994C>G p.S665* | Nonsense Mutation (SNP) | VAF 27/245 reads (11%) | catalogued as CM961195, CM992962, COSV101260447, COSV99059804; called by muse, mutect2, varscan2
- RTEL1 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs556575959; called by muse, mutect2, varscan2
- RYR1 | c.11810C>T p.S3937L | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1204208366, COSV100614124, COSV62104631; called by muse, mutect2
- SBF1 | c.2209C>G p.L737V | Missense Mutation (SNP) | VAF 58/426 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs1181565248; called by muse, mutect2, varscan2
- SETD1A | c.3547C>G p.P1183A | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); catalogued as rs140875864; called by muse, mutect2, varscan2
- SLC12A7 | c.2996C>G p.S999C | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV53758454; called by muse, mutect2
- SRGAP1 | c.1947G>C p.M649I | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61900746; called by muse, mutect2
- TAF1 | c.4387G>A p.E1463K (on ENST00000373790 / NM_138923.4; = p.E1484K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV52122671; called by muse, mutect2
- TBC1D4 | c.2786A>G p.Q929R | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.881); catalogued as rs771256412; called by muse, mutect2, varscan2
- TESPA1 | c.1312G>A p.A438T (on ENST00000316577 / NM_001098815.3; = p.A300T on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57257535; called by muse, mutect2, varscan2
- TRIM55 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52544186; called by muse, mutect2, varscan2
- USP54 | c.3458G>A p.R1153K | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100357645; called by muse, mutect2
- ZBTB20 | c.649G>A p.E217K (on ENST00000474710 / NM_001164342.2; = p.E144K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV61848638; called by muse, mutect2, varscan2
- ZNF142 | c.1246G>A p.E416K (on ENST00000411696 / NM_001379660.1; = p.E216K on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.583); catalogued as rs1423818988, COSV68743010; called by muse, mutect2
- ADAM22 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by mutect2, varscan2
- ADAMTS12 | c.2902A>T p.S968C | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ADGRL3 | c.474-1G>A p.X158_splice (on ENST00000506720 / NM_001322402.2; = p.X90_splice on NM_015236.6) | Splice Site (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- ARL2BP | c.21G>C p.E7D | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- C22orf39 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CELSR3 | c.4158C>G p.N1386K | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFAP44 | c.1998C>G p.I666M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.292); called by muse, varscan2
- CIT | c.2278C>G p.L760V | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CLSPN | c.3761C>T p.S1254L | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CUBN | c.9134C>G p.S3045C | Missense Mutation (SNP) | VAF 54/491 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.251); called by muse, varscan2
- DCAF1 | c.3242G>C p.R1081P | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- DDX17 | c.1715C>A p.S572* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | called by muse, varscan2
- DDX51 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DKK2 | c.201G>C p.K67N | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNA2 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DST | c.16816G>C p.E5606Q (on ENST00000361203 / NM_001374722.1; = p.E3303Q on NM_015548.5) | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- EFNB2 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 30/167 reads (18%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.2438C>A p.T813N | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EP300 | c.3979C>T p.H1327Y | Missense Mutation (SNP) | VAF 54/381 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPB41 | c.682-1G>A p.X228_splice (on ENST00000343067 / NM_001166005.2; = p.X19_splice on NM_004437.4) | Splice Site (SNP) | VAF 35/226 reads (15%) | called by muse, mutect2, varscan2
- ERCC3 | c.658-5C>T | Splice Region (SNP) | VAF 40/297 reads (13%) | called by muse, mutect2, varscan2
- EYS | c.7237A>G p.I2413V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FBXO7 | c.18del p.L7Ffs*2 | Frame Shift Del (DEL) | VAF 53/349 reads (15%) | called by mutect2, pindel, varscan2
- GAL3ST3 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GYPB | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 44/561 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); called by muse, mutect2
- HCRTR2 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HMGXB4 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ICE1 | c.6655G>A p.A2219T | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- IGFBP6 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- INTS2 | c.1600C>G p.H534D | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- IRX2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 40/805 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- KCND1 | c.792G>C p.M264I | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- KLHL15 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- LAMC2 | c.1690C>G p.P564A | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2
- LRP1B | c.3135A>T p.E1045D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK8IP2 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- NEDD4 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NLRP8 | c.2285G>C p.R762T | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, varscan2
- P3H1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- PAK2 | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PDCD6 | c.477G>A p.Q159= | Splice Region (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- PDE11A | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- PER1 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHKA2 | c.2986G>C p.E996Q | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); called by muse, mutect2
- POLQ | c.4102C>T p.Q1368* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- PRAMEF10 | c.440T>C p.L147S | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PRKACB | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.057); called by muse, mutect2
- RFWD3 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 66/410 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RNF180 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); called by muse, mutect2
- SAFB2 | c.2536G>C p.D846H | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SCN7A | c.4773G>C p.R1591S | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- SIN3B | c.2926G>T p.A976S | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- STRA8 | c.82G>A p.E28K (on ENST00000275764; = p.E6K on NM_182489.2) | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TET1 | c.3109C>T p.Q1037* | Nonsense Mutation (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- TRABD2B | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TTN | c.28272A>T p.Q9424H (on ENST00000591111; = p.Q8497H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/145 reads (14%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBD | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2
- ZHX1 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | called by muse, varscan2
- ZNF561-AS1 | n.135-1G>A | Splice Site (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- ZNF696 | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ABCC11 | c.2799C>T p.L933= | Silent (SNP) | VAF 16/346 reads (5%) | catalogued as COSV62321021; called by muse, mutect2
- CCDC85A | c.642C>T p.S214= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- CD151 | c.744C>G p.L248= | Silent (SNP) | VAF 9/254 reads (4%) | catalogued as COSV58989342; called by muse, mutect2
- CHD7 | c.3789G>A p.E1263= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV101418439; called by muse, varscan2
- CLPTM1L | c.388C>T p.L130= | Silent (SNP) | VAF 30/698 reads (4%) | called by muse, mutect2
- COL12A1 | c.3831C>T p.L1277= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV59390697; called by muse, mutect2, varscan2
- CORO6 | c.1371C>T p.I457= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as rs1357256416; called by muse, mutect2, varscan2
- CSMD2 | c.6256C>T p.L2086= | Silent (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- DLL3 | c.90C>T p.F30= | Silent (SNP) | VAF 39/272 reads (14%) | called by muse, mutect2, varscan2
- KCNQ1 | c.822C>T p.I274= | Silent (SNP) | VAF 28/424 reads (7%) | called by muse, mutect2
- KCTD3 | c.1779C>G p.L593= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, varscan2
- KLHL38 | c.552C>T p.L184= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs116917652, COSV58087236; called by muse, mutect2, varscan2
- MUC5B | c.11628C>G p.T3876= | Silent (SNP) | VAF 47/335 reads (14%) | called by muse, mutect2, varscan2
- NCAM1 | c.2157G>C p.L719= (on ENST00000316851 / NM_181351.5; = p.L709= on NM_000615.7) | Silent (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2, varscan2
- NIN | c.5328G>A p.Q1776= (on ENST00000382041 / NM_182946.1; = p.Q1063= on NM_016350.4) | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as rs373738252, COSV99813931; called by muse, mutect2, varscan2
- NRK | c.3897G>A p.L1299= | Silent (SNP) | VAF 27/247 reads (11%) | called by muse, mutect2, varscan2
- OSM | c.417G>A p.A139= | Silent (SNP) | VAF 49/245 reads (20%) | catalogued as rs148579514; called by muse, mutect2, varscan2
- POMGNT2 | c.759G>A p.P253= | Silent (SNP) | VAF 39/253 reads (15%) | catalogued as rs981484756, COSV100768015; called by muse, mutect2, varscan2
- PPAT | c.45C>T p.F15= | Silent (SNP) | VAF 42/327 reads (13%) | catalogued as rs774868196; called by muse, mutect2, varscan2
- PPFIA2 | c.1944G>A p.T648= | Silent (SNP) | VAF 33/240 reads (14%) | catalogued as rs764051148, COSV61036085; called by muse, mutect2, varscan2
- PSG8 | c.885C>T p.L295= | Silent (SNP) | VAF 16/467 reads (3%) | called by muse, mutect2
- PSMD2 | c.171G>A p.E57= | Silent (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- SOCS7 | c.1521C>T p.I507= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- TMC2 | c.1167G>A p.L389= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV62652956; called by muse, mutect2, varscan2
- TRIM6 | c.363G>C p.R121= | Silent (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- TRIO | c.2262C>T p.I754= | Silent (SNP) | VAF 38/594 reads (6%) | called by muse, mutect2
- TTC28 | c.4971G>C p.L1657= | Silent (SNP) | VAF 44/368 reads (12%) | called by muse, mutect2, varscan2
- UBQLNL | c.490T>C p.L164= | Silent (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- WDR41 | c.1203G>A p.L401= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV56998198; called by muse, varscan2
- XRRA1 | c.2256C>T p.F752= | Silent (SNP) | VAF 29/413 reads (7%) | catalogued as rs186896347; called by muse, mutect2
- ZNF628 | c.2901C>T p.T967= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs1265947516; called by muse, mutect2
- ADGRA1 | chr10:133084927 T>C | 5'Flank (SNP) | VAF 55/534 reads (10%) | called by muse, mutect2
- CCDC162P | n.3276+99C>G | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- CLEC12A | chr12:9986143 C>T | 3'Flank (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.172-35C>T | Intron (SNP) | VAF 22/135 reads (16%) | called by muse, varscan2
- MYO1F | c.3+25G>A | Intron (SNP) | VAF 27/236 reads (11%) | catalogued as rs782164608; called by muse, mutect2, varscan2
- NIBAN3 | c.1844-1490T>C | Intron (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2, varscan2
- NPHP1 | c.70-912G>A | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PCP4L1 | c.-24C>A | 5'UTR (SNP) | VAF 60/392 reads (15%) | called by muse, mutect2, varscan2
- PDCD6 | c.*109G>C | 3'UTR (SNP) | VAF 44/416 reads (11%) | called by muse, mutect2, varscan2
- PPP1R3A | c.-4C>A | 5'UTR (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- RPL13A | chr19:49487535 C>T | 5'Flank (SNP) | VAF 18/168 reads (11%) | catalogued as rs562307401; called by muse, mutect2
- SDR16C5 | c.836+1538G>C | Intron (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- SMOC2 | c.1323+677G>A | Intron (SNP) | VAF 27/169 reads (16%) | catalogued as rs564591295; called by muse, mutect2, varscan2
- SOCS2 | c.139+116C>G | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs1466191648; called by muse, mutect2, varscan2
- SUGCT | c.1089+2706C>G | Intron (SNP) | VAF 36/224 reads (16%) | catalogued as rs753142229; called by muse, mutect2, varscan2
- ZRSR2 | c.203+1455C>T | Intron (SNP) | VAF 6/107 reads (6%) | catalogued as rs1402448900; called by muse, mutect2
